Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CL-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]
Location: [REDACTED]

Taken: [REDACTED]

Gender: F
DOB: [REDACTED] (Age: [REDACTED])

MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

ICD-0-3
Carcinoma, squamous cell NOS
Site Cervix NOS
8070/3
055.9

DIAGNOSIS:

UTERUS, CERVIX, CURETTAGE
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

JW 8/27/13

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D., Ph.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D., Ph.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. [REDACTED]

[REDACTED] M.D.

History:

The patient is a [REDACTED] year old woman with history of cervical carcinoma. Operative procedure and findings: Cystoscopy with STENT placement and dilatation and curettage.

Specimen(s) Received:

A: CERVICAL TISSUE

Gross Description

Received in a formalin-filled container labeled with the patient's name and "Cervical tissue." It contains a tan-brown soft tissue fragment measuring 2.4 x 1.7 x 1.0 cm. Labeled A1. Jar 0.

[REDACTED] M.D.

This Surgical Pathology report is available on-line on

Physician Copy
END OF REPORT

Reviewer Initials: [REDACTED] Date Reviewed: 8/17/13		

Source: NCI Genomic Data Commons file 1c48306d-63a3-421d-9275-3d48d94d87b0 (TCGA-C5-A7CL.8AC84EA1-1A57-4263-9AA1-832DFAABBA08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).